Somatic mutation profile of tumor specimen C3N-03456-01 (aliquot CPT0246590006) from CPTAC case C3N-03456, project CPTAC-3 (Floor of mouth — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Floor of mouth, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 64.7 years (23,616 days).
Specimen C3N-03456-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Floor Of Mouth; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8167e008-8dfd-4eee-8e8b-8dba239652fa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03456-31 (Blood Derived Normal), aliquot CPT0246610002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d0acb1f8-ec41-46ea-a83d-0c0742b42358

The open-access MAF lists 110 somatic variants for this specimen: 77 protein-altering or splice-affecting, 20 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 65, Silent 20, Nonsense Mutation 5, 3'UTR 4, Frame Shift Del 3, Intron 3, Splice Region 2, RNA 2, 5'UTR 2, 3'Flank 1, 5'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- A2M | c.3554G>A p.R1185H | Missense Mutation (SNP) | VAF 113/420 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.756); catalogued as rs777433561; called by muse, mutect2, varscan2
- AICDA | c.532C>T p.R178C | Missense Mutation (SNP) | VAF 46/415 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV57563841, COSV99983919; called by muse, mutect2, varscan2
- ALPK1 | c.160G>A p.A54T | Missense Mutation (SNP) | VAF 52/206 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs751762758, COSV51584149; called by muse, mutect2, varscan2
- APCDD1L | c.599G>A p.R200H | Missense Mutation (SNP) | VAF 147/654 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV64485690; called by muse, mutect2, varscan2
- ASTN1 | c.1352A>C p.Q451P | Missense Mutation (SNP) | VAF 52/298 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as COSV99029680; called by muse, mutect2, varscan2
- C5orf51 | c.91G>A p.G31S | Missense Mutation (SNP) | VAF 75/226 reads (33%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as rs202010427; called by muse, mutect2, varscan2
- CEP295NL | c.1744G>A p.D582N | Missense Mutation (SNP) | VAF 70/414 reads (17%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.951); catalogued as rs749824611; called by muse, mutect2, varscan2
- CSMD3 | c.641C>A p.P214H | Missense Mutation (SNP) | VAF 163/381 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.934); catalogued as COSV99843764; called by muse, mutect2, varscan2
- CYP3A43 | c.1066C>G p.L356V | Missense Mutation (SNP) | VAF 38/157 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); catalogued as rs1319814062; called by muse, mutect2, varscan2
- DDB1 | c.2138G>T p.R713L | Missense Mutation (SNP) | VAF 63/339 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV57101018; called by muse, mutect2, varscan2
- DDHD1 | c.1108C>T p.P370S (on ENST00000323669; = p.P567S on NM_030637.3) | Missense Mutation (SNP) | VAF 62/396 reads (16%) | SIFT tolerated (0.61); PolyPhen benign (0.093); catalogued as COSV60357327; called by muse, mutect2, varscan2
- DUOXA1 | c.118G>A p.V40I | Missense Mutation (SNP) | VAF 31/187 reads (17%) | SIFT tolerated (0.84); PolyPhen benign (0.001); catalogued as rs552147039; called by muse, mutect2, varscan2
- EEF2 | c.1865T>A p.V622E | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV100500617; called by muse, mutect2, varscan2
- ELN | c.1477C>T p.P493S | Missense Mutation (SNP) | VAF 168/849 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.199); catalogued as rs1554682902; called by muse, mutect2, varscan2
- EPHB3 | c.526A>G p.T176A | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1161002948; called by muse, mutect2, varscan2
- EXO1 | c.2510G>A p.C837Y | Missense Mutation (SNP) | VAF 64/442 reads (14%) | SIFT tolerated, low confidence (0.84); PolyPhen benign (0); catalogued as rs1190836510; called by muse, mutect2, varscan2
- FCER2 | c.574G>A p.D192N | Missense Mutation (SNP) | VAF 47/170 reads (28%) | SIFT tolerated (0.29); PolyPhen benign (0.01); catalogued as COSV60916383; called by muse, mutect2, varscan2
- HAPLN2 | c.874G>T p.G292C | Missense Mutation (SNP) | VAF 139/671 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1042082297; called by muse, mutect2, varscan2
- KHSRP | c.1888G>A p.G630S | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as rs1355376332; called by muse, mutect2, varscan2
- LILRB3 | c.133G>A p.V45M | Missense Mutation (SNP) | VAF 94/636 reads (15%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.892); catalogued as rs746656873; called by muse, mutect2, varscan2
- MAGEB16 | c.721T>G p.F241V | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.188); catalogued as COSV67874315; called by muse, mutect2, varscan2
- MGAT4C | c.482C>T p.A161V | Missense Mutation (SNP) | VAF 31/115 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.904); catalogued as rs140499591; called by muse, mutect2, varscan2
- NOTCH1 | c.1147G>T p.E383* | Nonsense Mutation (SNP) | VAF 561/837 reads (67%) | catalogued as COSV53074387, COSV99490932; called by muse, mutect2, varscan2
- NUP205 | c.5423G>A p.R1808H | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs140045221, COSV53658976; called by muse, mutect2, varscan2
- OLFM3 | c.257T>G p.L86R (on ENST00000338858 / NM_001288821.1; = p.L66R on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/167 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58796124, COSV58798328; called by muse, mutect2, varscan2
- OR2L3 | c.521A>G p.N174S | Missense Mutation (SNP) | VAF 56/406 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.902); catalogued as rs150784625; called by muse, varscan2
- OR4A15 | c.617C>A p.A206D | Missense Mutation (SNP) | VAF 35/252 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.025); catalogued as rs775713952, COSV59035132; called by muse, mutect2, varscan2
- PALLD | c.1822A>T p.R608W | Missense Mutation (SNP) | VAF 63/248 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.502); catalogued as COSV54981081; called by muse, mutect2, varscan2
- PRKCZ | c.1687G>A p.D563N | Missense Mutation (SNP) | VAF 26/99 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.196); catalogued as rs901650050, COSV61598942; called by muse, mutect2, varscan2
- SCN9A | c.550C>T p.L184F | Missense Mutation (SNP) | VAF 65/344 reads (19%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.982); catalogued as COSV104409006; called by muse, mutect2, varscan2
- SPDYC | c.611G>A p.R204H | Missense Mutation (SNP) | VAF 35/227 reads (15%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs752699248; called by muse, mutect2, varscan2
- SYNCRIP | c.976A>G p.I326V | Missense Mutation (SNP) | VAF 48/275 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1352079569; called by muse, mutect2, varscan2
- TAF5L | c.649C>T p.R217C | Missense Mutation (SNP) | VAF 30/166 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.549); catalogued as rs145984199, COSV51092590; called by muse, mutect2, varscan2
- TP53 | c.154C>T p.Q52* | Nonsense Mutation (SNP) | VAF 147/246 reads (60%) | catalogued as COSV52734084, COSV53134595; called by muse, mutect2, varscan2
- TRIM32 | c.326G>A p.R109Q | Missense Mutation (SNP) | VAF 157/507 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.212); catalogued as rs748324526; called by muse, mutect2, varscan2
- TRIM49B | c.790C>A p.Q264K | Missense Mutation (SNP) | VAF 32/395 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.035); catalogued as rs1565093128; called by muse, mutect2, varscan2
- TXNDC2 | c.449C>A p.P150H (on ENST00000306084 / NM_001098529.2; = p.P83H on NM_032243.6) | Missense Mutation (SNP) | VAF 68/262 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.989); catalogued as COSV100045833; called by muse, varscan2
- WNK2 | c.6634G>A p.A2212T (on ENST00000297954 / NM_001282394.1; = p.A2175T on NM_006648.3) | Missense Mutation (SNP) | VAF 45/193 reads (23%) | SIFT tolerated (0.9); PolyPhen benign (0.029); catalogued as rs1313135952; called by muse, mutect2, varscan2
- ZER1 | c.1836G>C p.Q612H | Missense Mutation (SNP) | VAF 43/190 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV52566974; called by muse, mutect2, varscan2
- ZNF571 | c.298G>T p.G100W | Missense Mutation (SNP) | VAF 75/415 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV73897526; called by muse, mutect2, varscan2
- ARHGAP39 | c.2369_2371dup p.R790dup | In Frame Ins (INS) | VAF 29/116 reads (25%) | called by mutect2, pindel, varscan2
- CCNF | c.611A>T p.Q204L | Missense Mutation (SNP) | VAF 45/202 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- CCNF | c.2347C>G p.L783V | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- CDC20 | c.1127G>T p.G376V | Missense Mutation (SNP) | VAF 108/601 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL4A6 | c.4510G>A p.A1504T | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- COPS2 | c.1139_1140del p.I380Rfs*4 | Frame Shift Del (DEL) | VAF 39/133 reads (29%) | called by mutect2, pindel, varscan2
- EML3 | c.2096C>A p.S699Y | Missense Mutation (SNP) | VAF 84/261 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FBN1 | c.4000G>A p.G1334S | Missense Mutation (SNP) | VAF 177/474 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- FBN3 | c.1889C>T p.A630V | Missense Mutation (SNP) | VAF 82/314 reads (26%) | SIFT tolerated (0.97); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- FILIP1L | c.2135C>G p.S712* (on ENST00000354552 / NM_182909.3; = p.S472* on NM_014890.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 31/166 reads (19%) | called by muse, mutect2, varscan2
- GABRG2 | c.181G>A p.V61I | Missense Mutation (SNP) | VAF 45/299 reads (15%) | SIFT tolerated (0.78); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- GPR75 | c.297del p.M100Cfs*34 | Frame Shift Del (DEL) | VAF 24/149 reads (16%) | called by mutect2, pindel, varscan2
- IFT122 | c.2255C>G p.T752S (on ENST00000348417 / NM_052989.3; = p.T693S on NM_018262.4) | Missense Mutation (SNP) | VAF 188/454 reads (41%) | SIFT tolerated (0.76); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- IGDCC4 | c.3345C>T p.G1115= | Splice Region (SNP) | VAF 5/15 reads (33%) | called by muse, varscan2
- KLF16 | c.323C>T p.S108L | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0.003); called by muse, mutect2
- KMT2D | c.16480del p.I5494Sfs*15 | Frame Shift Del (DEL) | VAF 57/146 reads (39%) | called by mutect2, pindel, varscan2
- KNL1 | c.5A>G p.D2G | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); called by muse, mutect2
- MINDY1 | c.1329+8G>T | Splice Region (SNP) | VAF 240/579 reads (41%) | called by muse, varscan2
- MYH2 | c.5009A>G p.Q1670R | Missense Mutation (SNP) | VAF 319/566 reads (56%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- NDEL1 | c.875A>G p.N292S | Missense Mutation (SNP) | VAF 90/152 reads (59%) | SIFT tolerated (0.45); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PARD3B | c.2518A>G p.K840E (on ENST00000406610 / NM_001302769.2; = p.K771E on NM_057177.7) | Missense Mutation (SNP) | VAF 38/324 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- PIEZO1 | c.176T>A p.L59H | Missense Mutation (SNP) | VAF 55/320 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- PKN2 | c.2860G>T p.A954S | Missense Mutation (SNP) | VAF 43/232 reads (19%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- POLR3C | c.1467G>T p.E489D | Missense Mutation (SNP) | VAF 29/210 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.639); called by muse, mutect2, varscan2
- PPP1R10 | c.708C>A p.Y236* | Nonsense Mutation (SNP) | VAF 39/168 reads (23%) | called by muse, mutect2, varscan2
- PTPN6 | c.1750G>A p.D584N | Missense Mutation (SNP) | VAF 138/537 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RELN | c.8397dup p.C2800Mfs*15 | Frame Shift Ins (INS) | VAF 92/591 reads (16%) | called by mutect2, pindel, varscan2
- SDR39U1 | c.388G>T p.D130Y | Missense Mutation (SNP) | VAF 69/323 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SEMA5A | c.3197C>T p.T1066I | Missense Mutation (SNP) | VAF 54/524 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- SLC26A6 | c.583C>T p.Q195* | Nonsense Mutation (SNP) | VAF 18/34 reads (53%) | called by muse, mutect2, varscan2
- SLC35G4 | c.862T>C p.S288P | Missense Mutation (SNP) | VAF 92/280 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.879); called by muse, varscan2
- SRRM4 | c.1625G>C p.S542T | Missense Mutation (SNP) | VAF 116/562 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.269); called by muse, mutect2, varscan2
- TAF5 | c.641A>T p.Y214F | Missense Mutation (SNP) | VAF 37/223 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TAS1R2 | c.2036A>T p.Y679F | Missense Mutation (SNP) | VAF 144/683 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TECPR2 | c.2057G>T p.S686I | Missense Mutation (SNP) | VAF 60/157 reads (38%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- UNC79 | c.2486A>G p.K829R (on ENST00000393151 / NM_001346218.2; = p.K652R on NM_020818.5) | Missense Mutation (SNP) | VAF 32/144 reads (22%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- VCAM1 | c.85A>T p.T29S | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.25); called by muse, varscan2
- AUTS2 | c.2976G>A p.L992= | Silent (SNP) | VAF 59/335 reads (18%) | catalogued as rs1434315007; called by muse, mutect2, varscan2
- BMT2 | c.636C>G p.L212= | Silent (SNP) | VAF 19/62 reads (31%) | called by muse, mutect2, varscan2
- CEP350 | c.6450A>G p.K2150= | Silent (SNP) | VAF 19/122 reads (16%) | called by muse, mutect2, varscan2
- CKAP5 | c.3825A>G p.L1275= | Silent (SNP) | VAF 25/180 reads (14%) | called by muse, mutect2, varscan2
- FGGY | c.918G>A p.P306= | Silent (SNP) | VAF 28/159 reads (18%) | catalogued as rs148064306; called by muse, mutect2, varscan2
- MAP3K7CL | c.633G>A p.T211= | Silent (SNP) | VAF 110/253 reads (43%) | catalogued as rs370449217; called by muse, mutect2, varscan2
- METTL27 | c.6C>A p.A2= | Silent (SNP) | VAF 46/178 reads (26%) | called by muse, mutect2, varscan2
- MMP3 | c.235C>T p.L79= | Silent (SNP) | VAF 70/3049 reads (2%) | called by muse, mutect2
- MYH7 | c.714C>T p.N238= | Silent (SNP) | VAF 245/650 reads (38%) | catalogued as rs202141819, COSV62519883; ClinVar: benign / likely benign / uncertain significance; called by muse, mutect2, varscan2
- NCOA7 | c.2118C>T p.F706= | Silent (SNP) | VAF 74/160 reads (46%) | called by muse, mutect2, varscan2
- PAQR3 | c.885C>G p.V295= | Silent (SNP) | VAF 33/152 reads (22%) | called by muse, mutect2, varscan2
- PLXNB1 | c.220C>T p.L74= | Silent (SNP) | VAF 83/176 reads (47%) | catalogued as rs1258720980; called by muse, mutect2, varscan2
- PLXNB1 | c.219G>T p.V73= | Silent (SNP) | VAF 83/175 reads (47%) | called by muse, mutect2, varscan2
- POLR2C | c.39G>A p.E13= | Silent (SNP) | VAF 69/361 reads (19%) | called by muse, mutect2, varscan2
- PRRX1 | c.513C>T p.D171= | Silent (SNP) | VAF 36/239 reads (15%) | catalogued as rs374262561; called by muse, mutect2, varscan2
- RIPOR3 | c.2298C>T p.H766= | Silent (SNP) | VAF 134/366 reads (37%) | called by muse, mutect2, varscan2
- RPE65 | c.462G>A p.K154= | Silent (SNP) | VAF 59/377 reads (16%) | called by muse, mutect2, varscan2
- RPP30 | c.756A>G p.E252= | Silent (SNP) | VAF 60/109 reads (55%) | catalogued as rs1428167747; called by muse, mutect2, varscan2
- SLC12A3 | c.126C>T p.P42= | Silent (SNP) | VAF 108/518 reads (21%) | called by muse, mutect2, varscan2
- USH2A | c.4572A>G p.G1524= | Silent (SNP) | VAF 32/199 reads (16%) | called by muse, mutect2, varscan2
- BID | c.362-643C>T | Intron (SNP) | VAF 93/427 reads (22%) | catalogued as rs767571530; called by muse, mutect2, varscan2
- C1orf229 | n.244A>G | RNA (SNP) | VAF 63/116 reads (54%) | called by muse, mutect2, varscan2
- C4A | chr6:32006199 C>G | 3'Flank (SNP) | VAF 29/141 reads (21%) | catalogued as rs768476170; called by muse, mutect2, varscan2
- CCN5 | c.*24G>C | 3'UTR (SNP) | VAF 12/93 reads (13%) | catalogued as rs544099366; called by muse, mutect2, varscan2
- FAM205BP | n.1768G>A | RNA (SNP) | VAF 114/920 reads (12%) | catalogued as rs953787549; called by muse, mutect2, varscan2
- IPCEF1 | c.*54T>C | 3'UTR (SNP) | VAF 27/111 reads (24%) | called by muse, mutect2, varscan2
- LEAP2 | c.-12C>T | 5'UTR (SNP) | VAF 64/230 reads (28%) | catalogued as rs950820070; called by muse, mutect2, varscan2
- LMTK3 | c.*29C>T | 3'UTR (SNP) | VAF 51/208 reads (25%) | called by muse, mutect2, varscan2
- NFKBID | c.-185C>A | 5'UTR (SNP) | VAF 49/349 reads (14%) | called by muse, mutect2, varscan2
- SCIN | chr7:12570628 A>C | 5'Flank (SNP) | VAF 19/133 reads (14%) | called by muse, mutect2, varscan2
- SCIN | c.200-443G>T | Intron (SNP) | VAF 27/169 reads (16%) | called by muse, mutect2, varscan2
- TTN | c.10303+1313G>T | Intron (SNP) | VAF 42/156 reads (27%) | called by muse, mutect2, varscan2
- ZNF84 | c.*4202T>G | 3'UTR (SNP) | VAF 51/253 reads (20%) | called by muse, mutect2, varscan2
